Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A1FZ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A1FZ-01A (Primary Tumor).

[page 1 of 2]
Carcinoma, infiltrating duct, NOS 8500/3
Path - Site: breast, central portion C50.1
CQCF - Site: breast, NOS C50.9
1/25/11

Chief of

Phone

Fax

Specimen:

Received:

Spec Type: SURGICAL P

Status:

Subm Dr:

RT BR CA - INVASIVE

DATE:

DOCTOR(S):

PROCEDURE:

A. RT BR TISSUE

B. RT AX SENTINEL NODE #1

C. RT AX SENTINEL NODE #2

D. RT AX SENTINEL NODE #3

PART A RECEIVED LABELED [REDACTED] RIGHT BREAST, IS A SIMPLE MASTECTOMY SPECIMEN MEASURING 28 X 27 X 5.7 CM. THE NIPPLE IS UNREMARKABLE. THE SURROUNDING SKIN ELLIPSE MEASURES 25.5 X 16.3 CM. FOCAL BLUE DYE IS NOTED IN THE CENTRAL PORTION OF THE SKIN WHICH IS UPPER OUTER QUADRANT TO THE NIPPLE. A SUTURE DENOTES 12 O'CLOCK. ADDITIONALLY WITHIN THE CONTAINER IS A V-SHAPED PORTION OF SKIN WITH UNDERLYING FATTY TISSUE MEASURING 9.5 X 10 X 1.6 CM IN GREATEST DIMENSIONS. THIS IS NOT OTHERWISE ORIENTED. THE SUPERFICIAL ASPECT IS MARKED WITH BLUE INK, THE DEEP WITH BLACK INK. SECTIONING REVEALS BLAND YELLOW FATTY TISSUE WITH FINE FIBROUS BANDS AND A STELLATE PINK-GRAY FIBROUS LESION IN THE 9 O'CLOCK AREA MEASURING 2.2 X 1.7 X 3.0 CM FROM MEDIAL TO LATERAL. THIS IS ALSO IN THE CENTRAL PORTION OF THE BREAST. IT IS 2 CM FROM THE DEEP MARGIN AND 2 CM FROM THE SKIN AND THEREBY GREATER THAN 3 CM FROM ALL OTHER MARGINS. SECTIONS ARE SUBMITTED AS FOLLOWS: A1--NIPPLE (MIRROR IMAGE TO PROTOCOL), A2--DEEP MARGIN TO LESION, A3 AND 4--FULL CROSS-SECTION OF LESION, A5--LESION, A6 AND 7--FULL CROSS-SECTION OF LESION. NOTE THAT A5 THROUGH A7 ARE MIRROR IMAGE TO PROTOCOL SECTIONS AND NOTE THAT A7 IS IN AREA OF WING CLIP. A8--UPPER INNER QUADRANT, A9--UPPER OUTER QUADRANT, A10--LOWER OUTER QUADRANT, A11--LOWER INNER QUADRANT. NOTE: A8 THROUGH A11 ARE MIRROR IMAGES TO PROTOCOL SECTIONS. SECTIONING THE SEPARATELY SUBMITTED PORTION OF TISSUE REVEALS IT TO BE GROSSLY UNREMARKABLE, AND A REPRESENTATIVE SECTION AT THE POINT OF THE V IS SUBMITTED LABELED A12.

PART B RECEIVED LABELED [REDACTED] RIGHT AXILLA SENTINEL NODE #1, IS A 3 X 1.8 X 1.2 CM PORTION OF YELLOW FATTY TISSUE WITHIN WHICH IS A 1.5 CM CENTRALLY FAT-REPLACED GROSSLY UNREMARKABLE LYMPH NODE. THIS IS BISECTED AND SUBMITTED LABELED B.

PART C RECEIVED LABELED [REDACTED] RIGHT AXILLA SENTINEL NODE #2, IS A 3.7 X 2 X 1.3 CM IRREGULAR FRAGMENT OF YELLOW-RED FATTY TISSUE. SECTIONING REVEALS A GROSSLY FAT-REPLACED GROSSLY UNREMARKABLE LYMPH

[page 2 of 2]
Chief of Pathology

Phone

Fax

Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Req: [REDACTED]

Spec Type: SURGICAL P

Subm Dr:

(Continued)

NODE, SUBMITTED LABELED C1 THROUGH 3.

PART D RECEIVED LABELED [REDACTED], RIGHT AXILLA SENTINEL NODE #3, IS AN OVOID PORTION OF YELLOW FATTY TISSUE MEASURING 3 X 1.7 X 0.5 CM. SECTIONING REVEALS GROSSLY FAT-REPLACED NODAL TISSUE. THE SPECIMEN IS ENTIRELY SUBMITTED LABELED D.

PROCEDURES:

88307/4, IMMUNOPEROXIDAS/3, A BLK/12, BBX X6, CBX X6/3, DBX X6

PART A RIGHT SIMPLE MASTECTOMY: POORLY DIFFERENTIATED INFILTRATING DUCT CARCINOMA, NUCLEAR GRADE II/III WITH A MODERATE MITOTIC INDEX. THE TUMOR IS 22 MM IN MAXIMUM MICROSCOPIC DIMENSION. AREAS OF POSSIBLE LYMPHATIC SPACE INVASION ARE PRESENT, BUT THIS MAY ONLY BE RETRACTION ARTIFACT. ALL MARGINS ARE FREE OF TUMOR BY DISTANCES OF AT LEAST 20 MM.

PARTS B, C, AND D RIGHT AXILLARY SENTINEL LYMPH NODES NUMBERS 1-3, BIOPSIES: LYMPH NODES WITH NO EVIDENCE OF METASTATIC DISEASE, SUPPORTED BY NEGATIVE CYTOKERATIN IMMUNOHISTOCHEMICAL STAINING.

1

Signed _____

(prelim.)

_____(signature on file)_____

Source: NCI Genomic Data Commons file d6f65bbb-489a-4994-8051-62cf74b18006 (TCGA-A2-A1FZ.F93E326D-F4E0-4000-8A67-AA19C4D3637A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).